Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9ES, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9ES-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Melanoma, epithelioid & spindle
cell mixed

877013

Sate. Choroid C69.3

Uveal tract C69.4

JS 2/16/14

Enucleation of the right eye.

Macroscopy:

The eyeball measures 25 mm in diameter and the posterior optic nerve segment 10 mm. At the section, a brownish endo-ocular tumor measuring 15X15 mm main lines is observed. Tumor specimens have been taken for cryopreservation and genetic studies, and then the piece has been fixed and included entirely.

See path discrepancy form for epithelioid
and spindle cell ratio.

Microscopy

The tumor observed macroscopically presents the histological features of a melanoma. It is composed of a mix of epithelioid (50%) and fusiform cells (50%), with variable amounts of melanic pigment. These cells present an ovoid nucleus with moderate atypias, sometimes associated with visible nucleolus. The mitotic index is low (8 mitoses per 10 HPF).

Topographically, the tumor is located at distance of the endo-ocular emergence of the optic nerve. There is no scleral invasion and no tumor embolisms. The tumor infiltrates partially the ciliary body. At the posterior part of the eyeball, the lamina cribrosa, the optic nerve on its entire course and the meningeal sheaths are free of tumor. The cut end of the optic nerve is also free of tumor.

Conclusion:

Uveal melanoma composed of epithelioid and fusiform cells.

Tumor size: 15 mm main line.

Focal extension of the ciliary body.

No scleral or extra-scleral extension.

Optic nerve in its entire course and cut end, and meningeal sheaths free of tumor.

ICD-O Discrepancy		✓

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	50% epithelioid cells 50% spindle cells	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	61-90% epithelioid cells 1-30% spindle cells	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The section of the frozen sample used for sending to TCGA corresponds to a section of the tumor where the epithelioid part is predominant. The percentages mentioned on the initial Pathology Report correspond to an average on the whole embedded sections used for establish the Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 01574eb7-4796-45a4-91ab-88cbaabad43b (TCGA-V4-A9ES.D3687ED1-758F-45DE-B4FD-A91A5435F89B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).